Somatic mutation profile of tumor specimen TCGA-FS-A4FB-06A (aliquot TCGA-FS-A4FB-06A-11D-A25O-08) from TCGA case TCGA-FS-A4FB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 48.0 years (17,527 days).
Specimen TCGA-FS-A4FB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 885bd50e-754b-4ba6-a830-09094897bb2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4FB-10B (Blood Derived Normal), aliquot TCGA-FS-A4FB-10B-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eea87b16-a2ce-44cd-b449-4e3f646e17bf

The open-access MAF lists 218 somatic variants for this specimen: 148 protein-altering or splice-affecting, 64 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 64, Nonsense Mutation 8, Intron 3, Splice Region 3, RNA 2, Frame Shift Del 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA13 | c.4909G>A p.D1637N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV70032136; called by muse, mutect2, varscan2
- AC013489.1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183872; called by muse, mutect2, varscan2
- AC013489.1 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037133559, COSV99183873; called by muse, mutect2, varscan2
- ACO2 | c.2085C>A p.H695Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53443383; called by muse, mutect2, varscan2
- ADAT2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52794688; called by muse, mutect2, varscan2
- ADGRF4 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51953393; called by muse, mutect2, varscan2
- AMPD1 | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815074; called by muse, mutect2, varscan2
- AMPD1 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815077; called by muse, mutect2, varscan2
- ANO4 | c.2491C>T p.R831* (on ENST00000392977 / NM_001286615.2; = p.R796* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 42/51 reads (82%) | catalogued as rs145182702, COSV54586547; called by muse, mutect2, varscan2
- APOB | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV51939474; called by muse, mutect2, varscan2
- ARID4A | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV62164474; called by muse, mutect2
- ARSF | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV63839940; called by muse, mutect2, varscan2
- ASCL1 | c.341A>T p.Q114L | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as COSV57151882; called by muse, mutect2, varscan2
- C10orf82 | c.409T>A p.F137I | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65024663; called by muse, mutect2, varscan2
- CA1 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 87/116 reads (75%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs121909577, COSV56278928; called by muse, mutect2, varscan2
- CACNA1C | c.4841C>T p.T1614I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV59730451; called by muse, mutect2, varscan2
- CACNG2 | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV55636225; called by muse, mutect2, varscan2
- CATSPER1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.216); catalogued as rs745424701, COSV56411355; called by muse, mutect2, varscan2
- CCBE1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140934817, COSV67949898; called by muse, mutect2, varscan2
- CD163 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV63133589; called by muse, mutect2, varscan2
- CD1C | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV63806190, COSV63806719; called by muse, mutect2, varscan2
- CD276 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV59205565; called by muse, mutect2, varscan2
- CD99L2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV60936841; called by muse, mutect2, varscan2
- CDH17 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50330515; called by muse, mutect2, varscan2
- CEP170 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as rs1463735976, COSV60510234; called by muse, mutect2, varscan2
- CER1 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.8); PolyPhen benign (0.186); catalogued as rs1355632752, COSV66603498; called by muse, mutect2, varscan2
- CHST4 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs984927350, COSV58297458; called by muse, mutect2, varscan2
- CILP2 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52276062; called by muse, mutect2, varscan2
- COL12A1 | c.7091C>T p.S2364L | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59398089; called by muse, mutect2, varscan2
- CPED1 | c.2843G>A p.G948E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59997999; called by muse, mutect2, varscan2
- CREBZF | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs779903479, COSV52628888, COSV52630141; called by muse, mutect2, varscan2
- CSNK1G2 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.76); catalogued as rs754048888, COSV55337831; called by muse, mutect2, varscan2
- CWH43 | c.2022A>C p.R674S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV56939901; called by muse, mutect2
- DAB1 | c.1657G>A p.E553K (on ENST00000371231; = p.E520K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.461); catalogued as rs142236626; called by muse, mutect2, varscan2
- DDX53 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV60068454; called by muse, mutect2, varscan2
- DEPTOR | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV53817176; called by muse, mutect2, varscan2
- DGKB | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs533895069, COSV51791441; called by muse, mutect2, varscan2
- DMXL2 | c.7276C>T p.P2426S | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV51848433; called by muse, mutect2, varscan2
- DNAAF1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs144990549, CM129169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.7611G>A p.M2537I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV70230240; called by muse, mutect2, varscan2
- DOCK11 | c.3505C>T p.P1169S | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52241052; called by muse, mutect2, varscan2
- DUOXA1 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50993853; called by muse, mutect2, varscan2
- EPB41L1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754822027, COSV52435165; called by muse, mutect2, varscan2
- ESX1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.314); catalogued as rs782488534, COSV65424506; called by muse, mutect2, varscan2
- FABP2 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs367603528; called by muse, mutect2, varscan2
- FLNB | c.3649C>T p.P1217S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55882750; called by muse, mutect2, varscan2
- FRMPD2 | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV59719060; called by muse, mutect2, varscan2
- FRMPD3 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.06); catalogued as COSV99346480; called by muse, mutect2, varscan2
- GK2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62627336; called by muse, mutect2, varscan2
- GPR35 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as COSV60577531; called by muse, mutect2, varscan2
- GRIA2 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52394124; called by muse, mutect2, varscan2
- GRIN2A | c.3709G>A p.D1237N | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1389208302, COSV58038638; called by muse, mutect2, varscan2
- GRM2 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56585480; called by muse, mutect2
- GUCY2C | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV53791284; called by muse, mutect2, varscan2
- HABP2 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV63491481; called by muse, mutect2, varscan2
- HGF | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55951344; called by muse, mutect2, varscan2
- HMCN1 | c.10904G>A p.R3635Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs777872545, COSV54908505; called by muse, mutect2, varscan2
- HUWE1 | c.9482A>G p.H3161R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.888); catalogued as COSV53350066; called by muse, mutect2
- IGKV2D-30 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); catalogued as rs1259599818; called by muse, mutect2, varscan2
- IL17RD | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV56339173; called by muse, mutect2, varscan2
- IL1F10 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV61750670; called by muse, mutect2, varscan2
- INSR | c.1510T>C p.Y504H | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV100252472; called by muse, mutect2, varscan2
- IQCH | c.2298A>T p.K766N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV60054556; called by muse, mutect2, varscan2
- JAKMIP2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs934467542, COSV54599978; called by muse, mutect2, varscan2
- KCND2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV58584775; called by muse, mutect2, varscan2
- KDELR3 | c.643T>C p.*215Rext*13 | Nonstop Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV53248331; called by muse, mutect2, varscan2
- KRCC1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as COSV61251699; called by muse, mutect2, varscan2
- KRTAP5-9 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.038); catalogued as COSV73200206; called by muse, mutect2, varscan2
- LAMA3 | c.8042C>T p.S2681L (on ENST00000313654 / NM_198129.4; = p.S1072L on NM_000227.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs371915321, COSV52532872; called by muse, mutect2, varscan2
- LDAH | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs371645099; called by muse, mutect2, varscan2
- LEMD3 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 58/89 reads (65%) | catalogued as COSV57651158; called by muse, mutect2, varscan2
- LMAN1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195345; called by muse, mutect2, varscan2
- LMAN1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99195346; called by muse, mutect2, varscan2
- LOXL2 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs983170543, COSV101207921; called by muse, mutect2, varscan2
- LRCH2 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556553679, COSV57752750; called by muse, mutect2, varscan2
- LRP1B | c.10710G>A p.W3570* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV67233780; called by muse, mutect2, varscan2
- LRP2 | c.10580C>T p.P3527L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55558016, COSV99788341; called by muse, mutect2, varscan2
- MAN2B1 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV55472749; called by muse, mutect2, varscan2
- MCM8 | c.278_281del p.I93Rfs*22 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs777947820; called by pindel, varscan2
- MICB | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV52856836; called by muse, mutect2, varscan2
- MKRN3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV58810322; called by muse, mutect2, varscan2
- MLLT10 | c.2054T>A p.L685H (on ENST00000307729 / NM_001195626.3; = p.L701H on NM_004641.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56997694; called by muse, mutect2, varscan2
- MMRN1 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs745711366, COSV53338551; called by muse, mutect2, varscan2
- MROH8 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1346116815, COSV54120983; called by muse, mutect2, varscan2
- MTERF3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762868325, COSV54633052, COSV54634245; called by muse, mutect2, varscan2
- MTNR1A | c.999G>A p.W333* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV56156546; called by muse, mutect2, varscan2
- MXRA5 | c.7747G>A p.D2583N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs747665960, COSV54238737; called by muse, mutect2, varscan2
- MYH13 | c.4379G>A p.W1460* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs757204394, COSV52832005, COSV52835645; called by muse, mutect2, varscan2
- MYH9 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as rs1304469257, COSV53383079, COSV53387833; called by muse, mutect2, varscan2
- MYL2 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV57407179; called by muse, mutect2, varscan2
- MYO15A | c.3302C>T p.P1101L | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99233191; called by muse, varscan2
- MYO18B | c.7177G>A p.D2393N | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs751707031, COSV59137434; called by muse, mutect2, varscan2
- MYOCD | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58497540; called by muse, mutect2, varscan2
- MYOM3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs754148028, COSV58395269; called by muse, mutect2, varscan2
- NCOA3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765156127, COSV59069736; called by muse, mutect2, varscan2
- NLRP12 | c.2361G>A p.M787I | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60744722, COSV60745666; called by muse, mutect2, varscan2
- OAS2 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60802847; called by muse, mutect2, varscan2
- OR10H5 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); catalogued as COSV58278404; called by muse, mutect2, varscan2
- OR2L8 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV61727077; called by muse, mutect2, varscan2
- OR2W3 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV64457194; called by muse, mutect2, varscan2
- OR4K5 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs1305077423, COSV60003460; called by muse, mutect2, varscan2
- OR9A2 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV63306478, COSV63306739; called by muse, mutect2, varscan2
- PALMD | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.054); catalogued as COSV54165090; called by muse, mutect2, varscan2
- PCNX2 | c.5570G>A p.R1857K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV50812679; called by muse, mutect2, varscan2
- PCSK1 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs567748971, COSV60735982; called by muse, mutect2, varscan2
- PLCE1 | c.1666C>T p.L556F | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs541692822, COSV53353123, COSV53355116; called by muse, mutect2, varscan2
- PLS1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61834252; called by muse, mutect2, varscan2
- PLXNA3 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs201916270, COSV63753176; called by muse, mutect2, varscan2
- PMP2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.865); catalogued as rs758218348, COSV56267219; called by muse, mutect2, varscan2
- PRSS37 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63339557; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1746C>T p.D582= | Splice Region (SNP) | VAF 26/77 reads (34%) | catalogued as COSV52863642; called by muse, mutect2, varscan2
- ROCK1 | c.2441T>C p.L814S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV67696572; called by muse, mutect2, varscan2
- RYR1 | c.2516T>C p.V839A | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.497); catalogued as rs774243262, COSV62100373; called by muse, mutect2, varscan2
- SATB2 | c.659A>C p.Q220P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53486012; called by muse, mutect2, varscan2
- SCNN1G | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV55599542; called by muse, mutect2
- SIGLEC5 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55780614; called by muse, mutect2, varscan2
- SLC17A6 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.277); catalogued as COSV54137512; called by muse, mutect2
- SLC1A1 | c.720C>G p.F240L | Missense Mutation (SNP) | VAF 90/100 reads (90%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV52054124; called by muse, varscan2
- SLC25A18 | c.816G>A p.W272* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV53658528; called by muse, mutect2, varscan2
- SLC27A2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as rs776616450, COSV51059743; called by muse, mutect2, varscan2
- SLC4A1AP | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV58135390; called by muse, mutect2, varscan2
- SLFN11 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57698484; called by muse, mutect2, varscan2
- SPHKAP | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs867230597, COSV60882848; called by muse, mutect2, varscan2
- SPR | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52298040; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | PolyPhen possibly damaging (0.483); catalogued as rs746641827, COSV50073490; called by muse, mutect2, varscan2
- STAG2 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV54354453; called by muse, mutect2, varscan2
- STK36 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.239); catalogued as COSV55327447; called by muse, mutect2, varscan2
- TCHHL1 | c.44T>C p.F15S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV64286112; called by muse, mutect2, varscan2
- TESPA1 | c.551G>A p.R184Q (on ENST00000316577 / NM_001098815.3; = p.R46Q on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751647202, COSV57258688; called by muse, mutect2, varscan2
- TLR5 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.318); catalogued as COSV60558824; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2, varscan2
- TPTE | c.1346G>A p.G449E (on ENST00000618007 / NM_199261.4; = p.G431E on NM_199259.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs749783984; called by muse, mutect2, varscan2
- TRAK2 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV60272799; called by muse, mutect2, varscan2
- TRIOBP | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs374237291, COSV60376639; called by muse, mutect2, varscan2
- TRPM5 | c.117G>A p.K39= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV50157848, COSV99330767; called by muse, mutect2, varscan2
- TRPS1 | c.22C>T p.P8S (on ENST00000220888 / NM_001330599.2; = p.P21S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.27); catalogued as COSV55246251; called by muse, mutect2, varscan2
- TUBA3C | c.225C>T p.V75= | Splice Region (SNP) | VAF 18/36 reads (50%) | catalogued as rs762583240, COSV67139468; called by muse, mutect2, varscan2
- UBASH3A | c.1535T>G p.F512C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52311389; called by muse, mutect2, varscan2
- UIMC1 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1349710982, COSV65893855; called by muse, mutect2, varscan2
- UPP1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1008827323, COSV57977779; called by muse, mutect2, varscan2
- VPS51 | c.2218T>C p.W740R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54207910; called by muse, mutect2, varscan2
- WIPF2 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs772620082, COSV60274089; called by muse, mutect2, varscan2
- ZDHHC15 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs774534195, COSV64900533; called by muse, mutect2, varscan2
- ZNF385D | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1189602032, COSV55749213; called by muse, mutect2, varscan2
- ZNF536 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs762646976, COSV62820064, COSV62833089; called by muse, mutect2, varscan2
- ZNF98 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV63337298; called by muse, mutect2, varscan2
- GOLM2 | c.545del p.K182Sfs*2 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | called by mutect2, pindel, varscan2
- ADAM28 | c.1086G>A p.V362= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV56101611; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1062G>C p.L354= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV56475688, COSV99836138; called by muse, mutect2
- APOB | c.7923C>T p.I2641= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as rs868050335, COSV51937168; called by muse, mutect2, varscan2
- ARHGEF3 | c.1389C>T p.S463= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs529702823, COSV56328088; called by muse, mutect2, varscan2
- ARSF | c.651C>T p.L217= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs868046794, COSV63839933; called by muse, mutect2, varscan2
- CACNA1E | c.1185C>T p.L395= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs186789666, COSV62385238; called by muse, mutect2
- CDH16 | c.705G>A p.E235= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV55337213; called by muse, mutect2, varscan2
- CELSR3 | c.3693C>T p.S1231= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV50884205; called by muse, mutect2, varscan2
- CFHR5 | c.699G>A p.V233= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV56823013; called by muse, mutect2, varscan2
- COL28A1 | c.1611C>T p.G537= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV68082715; called by muse, mutect2, varscan2
- COMMD4 | c.579C>T p.T193= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1418132548, COSV51190584; called by muse, mutect2, varscan2
- CTNNA2 | c.165G>A p.K55= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV63575262, COSV63575403; called by muse, mutect2, varscan2
- DENND1C | c.2010C>T p.P670= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV57568848; called by muse, mutect2, varscan2
- FLRT2 | c.1752G>A p.R584= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV58143834; called by muse, mutect2, varscan2
- GABRA4 | c.531G>A p.V177= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV51922717, COSV51928508; called by muse, mutect2, varscan2
- GPR179 | c.798G>A p.R266= (on ENST00000621958; = p.R265= on NM_001004334.4) | Silent (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- HMCN1 | c.3516G>A p.K1172= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV54908497; called by muse, mutect2, varscan2
- IL18RAP | c.1731G>A p.R577= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV51826683; called by muse, mutect2, varscan2
- INSR | c.1509T>C p.S503= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100252477; called by muse, mutect2, varscan2
- INSR | c.219C>T p.F73= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV57164632; called by muse, mutect2, varscan2
- ITGAX | c.2064C>T p.P688= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV51644210; called by muse, mutect2, varscan2
- KCNC4 | c.1770C>T p.F590= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV63925843; called by muse, mutect2, varscan2
- KLK8 | c.546G>A p.K182= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV51592444; called by muse, mutect2, varscan2
- KRT6B | c.705G>A p.L235= | Silent (SNP) | VAF 60/155 reads (39%) | catalogued as rs751621723, COSV52884244; called by muse, mutect2, varscan2
- LOXL2 | c.786C>A p.S262= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101207752, COSV101207920; called by muse, mutect2, varscan2
- MAP1B | c.6252C>T p.L2084= | Silent (SNP) | VAF 65/76 reads (86%) | catalogued as rs935421789, COSV57100737; called by muse, mutect2, varscan2
- MED13 | c.6063T>C p.G2021= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV67264240; called by muse, mutect2, varscan2
- MROH9 | c.1635C>T p.F545= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100882802; called by muse, mutect2, varscan2
- MUC4 | c.2931T>A p.L977= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV62156721; called by muse, mutect2, varscan2
- MYO15A | c.3303C>T p.P1101= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV99233192; called by muse, varscan2
- NECTIN4 | c.936C>T p.I312= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV63513028; called by muse, mutect2, varscan2
- NFIX | c.1113C>T p.F371= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs768217315, COSV62178135; called by muse, mutect2, varscan2
- NLRP1 | c.2094G>A p.R698= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV52558713; called by muse, mutect2, varscan2
- NRG3 | c.1554C>T p.I518= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV64567802, COSV64584945, COSV64587364; called by muse, mutect2, varscan2
- OR10A5 | c.408C>T p.I136= | Silent (SNP) | VAF 53/82 reads (65%) | catalogued as COSV55054574; called by muse, mutect2, varscan2
- OR1J2 | c.643C>T p.L215= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as COSV58944511; called by muse, mutect2, varscan2
- OR2T4 | c.136C>T p.L46= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as COSV100822579, COSV63544236; called by muse, mutect2, varscan2
- OR2T6 | c.474C>T p.L158= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV63216523; called by muse, mutect2, varscan2
- OR4L1 | c.132C>T p.L44= | Silent (SNP) | VAF 59/113 reads (52%) | catalogued as rs773262429, COSV59850270; called by muse, mutect2, varscan2
- OSBPL3 | c.1533G>A p.R511= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV57657880; called by muse, mutect2, varscan2
- PDE4DIP | c.1398C>T p.T466= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV57700790; called by muse, mutect2, varscan2
- PGAP3 | c.402C>T p.P134= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1489113171, COSV56130200; called by muse, mutect2, varscan2
- PIGU | c.822C>T p.F274= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV54163542, COSV54166324; called by muse, mutect2, varscan2
- PLCB1 | c.3650G>A p.*1217= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV62036601, COSV62040931; called by muse, mutect2, varscan2
- PRAMEF10 | c.336C>T p.F112= | Silent (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
- PRKCZ | c.84C>T p.I28= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- PTHLH | c.393G>A p.G131= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV52368124; called by muse, mutect2, varscan2
- PTK2 | c.400C>T p.L134= | Silent (SNP) | VAF 57/84 reads (68%) | catalogued as COSV61787263, COSV61789489; called by muse, mutect2, varscan2
- RANBP3L | c.183A>C p.A61= | Silent (SNP) | VAF 45/53 reads (85%) | catalogued as COSV56956204; called by muse, mutect2, varscan2
- RELN | c.699G>A p.A233= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs780491620, COSV58988520, COSV58993933; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN3A | c.1191G>A p.G397= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV51801401; called by muse, mutect2, varscan2
- SCNN1B | c.783C>T p.F261= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs1287111905, COSV56305735; called by muse, mutect2, varscan2
- SEC14L3 | c.228C>T p.P76= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV53179859; called by muse, mutect2, varscan2
- SLC1A1 | c.675C>G p.V225= | Silent (SNP) | VAF 108/117 reads (92%) | catalogued as rs987990906, COSV52054106; called by muse, varscan2
- SLC25A12 | c.879C>T p.A293= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV55534189; called by muse, mutect2, varscan2
- SLFN11 | c.687G>A p.R229= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100390711; called by muse, mutect2, varscan2
- SNAI3 | c.315C>T p.L105= | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as COSV60002935; called by muse, mutect2, varscan2
- SYT3 | c.219C>T p.F73= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs188802553, COSV58897276; called by muse, mutect2, varscan2
- TBX19 | c.864C>T p.H288= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs769885677, COSV100892363; called by muse, mutect2, varscan2
- TBX19 | c.865C>A p.R289= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV100892364; called by muse, mutect2, varscan2
- TEX101 | c.76C>T p.L26= (on ENST00000598265 / NM_001130011.3; = p.L44= on NM_031451.4) | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53662184; called by muse, mutect2, varscan2
- TNS3 | c.2409C>T p.A803= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV60792820; called by muse, mutect2, varscan2
- TTN | c.13518G>A p.V4506= (on ENST00000591111; = p.V3579= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV60128418; called by muse, mutect2, varscan2
- ZC3H4 | c.3729C>T p.P1243= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs957811895, COSV53413712; called by muse, mutect2, varscan2
- IFIT2 | c.-1C>T | 5'UTR (SNP) | VAF 23/30 reads (77%) | catalogued as rs1331370025, COSV99260445; called by muse, mutect2, varscan2
- MIR519E | n.2C>T | RNA (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- PRR12 | c.52-388C>T | Intron (SNP) | VAF 10/24 reads (42%) | catalogued as COSV69817988; called by muse, mutect2, varscan2
- RIMS2 | c.177-44392G>A | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- SNORD116-15 | n.51G>A | RNA (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.10303+2367C>T | Intron (SNP) | VAF 16/49 reads (33%) | catalogued as rs1267288273, COSV60328288; called by muse, mutect2, varscan2
